Somatic mutation profile of tumor specimen TCGA-DD-A118-01A (aliquot TCGA-DD-A118-01A-11D-A12Z-10) from TCGA case TCGA-DD-A118, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 77.8 years (28,406 days).
Specimen TCGA-DD-A118-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 145a3d04-7f86-4f8b-af58-278d29108ba8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A118-11A (Solid Tissue Normal), aliquot TCGA-DD-A118-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/697c9205-15e4-4d85-a26f-48df669b2a9d

The open-access MAF lists 130 somatic variants for this specimen: 98 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 30, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 3, Intron 2, Frame Shift Ins 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 60/102 reads (59%) | catalogued as rs776240891, COSV56230964; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 32/195 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.1459A>T p.K487* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV53570509; called by muse, mutect2, varscan2
- ARSD | c.863+1G>A p.X288_splice | Splice Site (SNP) | VAF 34/131 reads (26%) | catalogued as COSV54198330; called by muse, mutect2, varscan2
- ASB10 | c.446G>A p.R149H (on ENST00000420175 / NM_001142459.2; = p.R134H on NM_080871.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs767142527, COSV51994400; called by muse, mutect2, varscan2
- ATM | c.8654T>A p.L2885H | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53727818, COSV99591674; called by muse, mutect2, varscan2
- AUTS2 | c.312A>C p.K104N | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61384813; called by muse, mutect2, varscan2
- B9D1 | c.220T>A p.F74I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52069059; called by muse, mutect2, varscan2
- BHMT2 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs764785479, COSV54871902; called by muse, mutect2
- BNIP2 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs762238174, COSV51105148; called by muse, mutect2, varscan2
- BSN | c.1840A>G p.T614A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56513321; called by muse, mutect2, varscan2
- C14orf39 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV58779682; called by muse, mutect2, varscan2
- C1S | c.200A>C p.Y67S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61070143; called by muse, mutect2, varscan2
- CAMTA1 | c.1756T>G p.F586V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV57883118; called by muse, mutect2
- CCDC185 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100838757; called by muse, mutect2, varscan2
- CD1D | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as COSV63808444; called by muse, mutect2, varscan2
- CD47 | c.125T>G p.F42C | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62526688; called by muse, mutect2, varscan2
- CDH26 | c.1112T>A p.L371H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV54842997; called by muse, mutect2, varscan2
- CHCHD6 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.173); catalogued as COSV52058022; called by muse, mutect2, varscan2
- CSTF2 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV63376111; called by muse, mutect2, varscan2
- DMBT1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.219); catalogued as COSV57535250; called by muse, mutect2
- DNASE2 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV53434517; called by muse, mutect2, varscan2
- DOCK11 | c.4841C>T p.T1614I | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764343134, COSV52234031, COSV99353889; called by muse, mutect2, varscan2
- DRC7 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV61053164; called by muse, mutect2, varscan2
- DUSP6 | c.1145G>T p.*382Lext*36 | Nonstop Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV54378040; called by muse, mutect2, varscan2
- EFHC2 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69552809; called by muse, mutect2, varscan2
- ENAM | c.1150C>G p.P384A | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV68535285; called by muse, mutect2, varscan2
- EPGN | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV59740310; called by muse, mutect2, varscan2
- ERBB3 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57247433; called by muse, mutect2, varscan2
- FAT2 | c.3946-1G>C p.X1316_splice | Splice Site (SNP) | VAF 15/87 reads (17%) | catalogued as COSV55814089; called by muse, mutect2, varscan2
- FLG | c.5837C>T p.A1946V | Missense Mutation (SNP) | VAF 140/676 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs774117765, COSV64236215; called by muse, mutect2, varscan2
- FN1 | c.4654G>A p.D1552N | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs140153061, COSV60547202; called by muse, mutect2, varscan2
- GALNT6 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs1324961687, COSV62541683, COSV62542342; called by muse, mutect2, varscan2
- GNA15 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as COSV53585065; called by muse, mutect2, varscan2
- GPR142 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV100170712, COSV59518631; called by muse, mutect2, varscan2
- GPR63 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV57739693; called by muse, mutect2, varscan2
- GPRASP1 | c.3086C>T p.T1029M | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs760692354, COSV64354858; called by muse, mutect2, varscan2
- GRIA3 | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 93/486 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV52050068; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554348257, COSV56084565; called by muse, mutect2, varscan2
- H4C2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV55137627, COSV55138037; called by muse, mutect2, varscan2
- H4C5 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.378); catalogued as COSV63486191; called by muse, mutect2, varscan2
- IGSF9 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV63638836; called by muse, mutect2, varscan2
- IL13RA1 | c.826T>A p.Y276N | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.049); catalogued as COSV65426091; called by muse, mutect2, varscan2
- IL6ST | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 76/296 reads (26%) | catalogued as COSV61139808; called by muse, mutect2, varscan2
- IMMT | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.692); catalogued as rs754210825, COSV54485579; called by muse, mutect2, varscan2
- IQSEC2 | c.2083G>A p.D695N (on ENST00000642864 / NM_001111125.3; = p.D490N on NM_015075.2) | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV64723679; called by muse, mutect2, varscan2
- ITIH3 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762580849, COSV69647999; called by muse, mutect2, varscan2
- JAM2 | c.712A>G p.S238G | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs201705901; called by muse, mutect2, varscan2
- KIAA1522 | c.1121C>T p.S374F (on ENST00000373480 / NM_001198972.2; = p.S433F on NM_020888.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53862518; called by muse, mutect2, varscan2
- KLHL21 | c.1009A>T p.I337F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV66552989; called by muse, mutect2, varscan2
- LARGE1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255313940, COSV61658079; called by muse, mutect2, varscan2
- LBR | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55287543; called by muse, mutect2, varscan2
- LRP1B | c.4982G>A p.R1661H | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs756168629, COSV67189242, COSV67241168; called by muse, mutect2, varscan2
- MAP3K14 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV60922744; called by muse, mutect2, varscan2
- MMP15 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs372389085, COSV54678787; called by muse, mutect2, varscan2
- MSN | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs748200741, COSV64303313; called by muse, mutect2, varscan2
- MTMR3 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV60301995; called by muse, mutect2, varscan2
- MYH11 | c.4636A>G p.T1546A | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV55545414; called by muse, mutect2, varscan2
- MYOCD | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58497670; called by muse, mutect2, varscan2
- NEK6 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57216110; called by muse, mutect2, varscan2
- NFATC4 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as rs755075807, COSV51596936; called by muse, mutect2, varscan2
- NFE2L1 | c.485dup p.V163Sfs*14 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs773403681; called by mutect2, varscan2
- NMU | c.248T>G p.F83C | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV51698780; called by muse, mutect2, varscan2
- NOS2 | c.2824G>A p.G942S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58221972; called by muse, mutect2, varscan2
- NOTCH4 | c.2314G>T p.V772L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV66678913; called by muse, mutect2, varscan2
- NPY5R | c.108T>G p.S36R | Missense Mutation (SNP) | VAF 81/339 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV58451074; called by muse, mutect2, varscan2
- OAS1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 85/281 reads (30%) | catalogued as COSV52534256; called by muse, mutect2, varscan2
- OR10X1 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.433); catalogued as COSV63766976; called by muse, mutect2, varscan2
- OR51G1 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV58968518; called by muse, mutect2, varscan2
- PCDHA8 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.214); catalogued as COSV65334962; called by muse, mutect2, varscan2
- POLE | c.2624A>C p.N875T | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as COSV57674778; called by muse, mutect2, varscan2
- RAB9A | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54610526; called by muse, mutect2, varscan2
- RBM33 | c.3056A>T p.Q1019L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV62030738; called by muse, mutect2, varscan2
- REC8 | c.737+1G>T p.X246_splice | Splice Site (SNP) | VAF 49/211 reads (23%) | catalogued as COSV61015238, COSV61017559; called by muse, mutect2, varscan2
- RPP30 | c.286A>G p.R96G | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as COSV53295261; called by muse, mutect2, varscan2
- SERPINE1 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56168748; called by muse, mutect2, varscan2
- SEZ6L | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); catalogued as COSV50658308; called by muse, mutect2, varscan2
- SLC17A6 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54133680; called by muse, mutect2, varscan2
- SV2A | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs200303127, COSV100975182, COSV64964284; called by muse, mutect2, varscan2
- TBC1D8 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100964304; called by muse, mutect2, varscan2
- TCEAL4 | c.437A>T p.H146L | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV65463085; called by muse, mutect2, varscan2
- THRAP3 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 65/202 reads (32%) | catalogued as COSV63566721; called by muse, mutect2, varscan2
- TREX2 | c.239G>A p.R80H (on ENST00000334497; = p.R37H on NM_080701.3) | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs782408064, COSV100444294, COSV57847905; called by muse, mutect2, varscan2
- TTN | c.65191C>G p.P21731A (on ENST00000591111; = p.P14307A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | PolyPhen probably damaging (0.997); catalogued as COSV59901850; called by muse, mutect2, varscan2
- TUBA8 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as rs754887058, COSV57812394; called by muse, mutect2, varscan2
- VAT1L | c.601T>A p.C201S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV56814829, COSV56825172; called by muse, mutect2, varscan2
- VWA3B | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV68241042, COSV68244910; called by muse, mutect2, varscan2
- ZBED1 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs199678782, COSV58130393; called by muse, mutect2, varscan2
- ZCCHC4 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 39/294 reads (13%) | catalogued as COSV57180341; called by muse, mutect2, varscan2
- ZFHX4 | c.6325C>T p.L2109F | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50511284; called by muse, mutect2, varscan2
- ZNF208 | c.2287A>G p.T763A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.68); catalogued as COSV68101075; called by muse, mutect2, varscan2
- ZNF208 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV68101092; called by muse, mutect2, varscan2
- ZNF540 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100329754, COSV57108094; called by muse, mutect2, varscan2
- ZNF804B | c.2573C>A p.S858* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | catalogued as COSV60817301; called by muse, mutect2, varscan2
- ACCS | c.88dup p.E30Gfs*23 | Frame Shift Ins (INS) | VAF 12/112 reads (11%) | called by mutect2, pindel, varscan2
- DST | c.15111_15118del p.K5037Nfs*9 (on ENST00000361203 / NM_001374722.1; = p.K2625Nfs*9 on NM_015548.5) | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- FHOD3 | c.1358del p.E453Gfs*21 | Frame Shift Del (DEL) | VAF 103/221 reads (47%) | called by mutect2, pindel, varscan2
- MIA3 | c.2096del p.G699Afs*4 | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel, varscan2
- AC127029.3 | c.627G>A p.V209= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV60110312; called by muse, mutect2, varscan2
- ACTR3B | c.963C>G p.L321= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as COSV55446461; called by muse, mutect2, varscan2
- ARHGEF18 | c.1086C>T p.T362= (on ENST00000359920 / NM_001130955.2; = p.T258= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs1302340069, COSV60467198; called by muse, varscan2
- ARMCX5-GPRASP2 | c.1446C>A p.I482= | Silent (SNP) | VAF 215/526 reads (41%) | catalogued as COSV63437144; called by muse, mutect2, varscan2
- CCDC185 | c.792G>T p.L264= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as COSV100838758; called by muse, mutect2, varscan2
- CEACAM16 | c.219C>A p.G73= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs534225927, COSV69186207; called by muse, mutect2, varscan2
- DLGAP5 | c.2334C>A p.I778= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as COSV55962140; called by muse, mutect2, varscan2
- DNASE2 | c.795T>G p.S265= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV52241409; called by muse, mutect2, varscan2
- GABRQ | c.129C>T p.V43= | Silent (SNP) | VAF 45/224 reads (20%) | catalogued as COSV64780946; called by muse, mutect2, varscan2
- KLF11 | c.690C>T p.S230= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs777257289, COSV59940022; called by muse, mutect2, varscan2
- KLRK1 | c.36C>T p.S12= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV53698015; called by muse, mutect2, varscan2
- LRRC32 | c.696C>A p.A232= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV52631628; called by muse, mutect2, varscan2
- MDN1 | c.14463A>G p.S4821= | Silent (SNP) | VAF 135/523 reads (26%) | catalogued as COSV65517547; called by muse, mutect2, varscan2
- MUC16 | c.4569C>A p.I1523= | Silent (SNP) | VAF 52/285 reads (18%) | catalogued as COSV67447015; called by muse, mutect2, varscan2
- NASP | c.2217G>A p.P739= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1423861702, COSV59645897; called by muse, mutect2, varscan2
- NFS1 | c.168G>A p.L56= | Silent (SNP) | VAF 46/295 reads (16%) | catalogued as COSV60763900; called by muse, mutect2, varscan2
- NLGN4X | c.1986T>C p.T662= | Silent (SNP) | VAF 304/826 reads (37%) | catalogued as COSV52005474; called by muse, mutect2, varscan2
- OR52M1 | c.628T>C p.L210= | Silent (SNP) | VAF 73/339 reads (22%) | catalogued as COSV64171489; called by muse, mutect2, varscan2
- PCDHA7 | c.2118G>T p.A706= | Silent (SNP) | VAF 253/443 reads (57%) | catalogued as rs1554136017, COSV65334957; called by muse, mutect2, varscan2
- PDE8A | c.1554T>A p.G518= | Silent (SNP) | VAF 85/371 reads (23%) | catalogued as COSV59634912, COSV59640922; called by muse, mutect2, varscan2
- PIWIL1 | c.279A>G p.T93= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs752244660, COSV55344405; called by muse, mutect2, varscan2
- SBNO2 | c.3249G>A p.A1083= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs781001227, COSV62318760; called by muse, mutect2, varscan2
- SLC8A1 | c.1350A>T p.T450= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV60471812; called by muse, mutect2, varscan2
- SYMPK | c.3627C>T p.D1209= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV55570114; called by muse, mutect2, varscan2
- TBC1D8 | c.711G>T p.L237= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as COSV100964305; called by muse, mutect2, varscan2
- TCOF1 | c.3180T>C p.T1060= (on ENST00000377797 / NM_001135243.1; = p.T983= on NM_000356.4) | Silent (SNP) | VAF 82/146 reads (56%) | catalogued as rs902192448, COSV60345924; called by muse, varscan2
- USH2A | c.7476G>A p.S2492= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs777803742, COSV56331334; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZDHHC17 | c.438T>C p.Y146= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs376206630; called by muse, mutect2, varscan2
- ZDHHC5 | c.1266C>T p.S422= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs1242588732, COSV54705163; called by muse, mutect2, varscan2
- ZNF449 | c.786G>A p.L262= | Silent (SNP) | VAF 66/439 reads (15%) | catalogued as COSV59346201; called by muse, mutect2, varscan2
- RAB18 | c.68+658T>C | Intron (SNP) | VAF 62/161 reads (39%) | called by muse, mutect2, varscan2
- RBM33 | c.949-27C>A | Intron (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
